Somatic mutation profile of tumor specimen TCGA-MH-A560-01A (aliquot TCGA-MH-A560-01A-11D-A26P-10) from TCGA case TCGA-MH-A560, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 62.6 years (22,866 days).
Specimen TCGA-MH-A560-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e5a8b7d-adf7-48ac-9209-9ac400069a30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MH-A560-10A (Blood Derived Normal), aliquot TCGA-MH-A560-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95d19e49-0035-42da-b596-f45717cd5085

The open-access MAF lists 55 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 2, Splice Region 1, RNA 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGO3 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 91/235 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV55794671; called by muse, mutect2, varscan2
- AMACR | c.476T>C p.M159T | Missense Mutation (SNP) | VAF 129/344 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as rs147265006, COSV59460708, COSV59461786; called by muse, varscan2
- C11orf53 | c.556A>C p.S186R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs1347922021, COSV54722039; called by muse, mutect2, varscan2
- CACNG2 | c.41C>A p.T14N | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55637362; called by muse, mutect2, varscan2
- CAPN2 | c.1990C>G p.R664G | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.09); catalogued as COSV54337515; called by muse, mutect2, varscan2
- CENPF | c.3694G>T p.E1232* | Nonsense Mutation (SNP) | VAF 28/104 reads (27%) | catalogued as COSV65275734; called by muse, varscan2
- CLDN11 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV50355699; called by muse, mutect2
- COL8A1 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 77/107 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53737399; called by muse, mutect2, varscan2
- CREB3L3 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV50207473, COSV50221297; called by muse, mutect2, varscan2
- CRIP3 | c.400+5_400+8del | Splice Region (DEL) | VAF 12/48 reads (25%) | catalogued as rs761139953; called by pindel, varscan2
- CUL1 | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV57389997; called by muse, mutect2, varscan2
- DEFA6 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs371286175; called by muse, mutect2, varscan2
- DHTKD1 | c.1425G>C p.E475D | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs773172105, COSV53804769; called by muse, mutect2, varscan2
- DNA2 | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.527); catalogued as rs369018277; called by muse, mutect2, varscan2
- DYNC2H1 | c.2440A>G p.K814E | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV62098743; called by muse, mutect2, varscan2
- HELZ | c.3871A>C p.I1291L | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62379348; called by muse, mutect2, varscan2
- INTS3 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 31/88 reads (35%) | catalogued as COSV59679243, COSV59682673; called by muse, mutect2, varscan2
- ITPRID2 | c.1438C>G p.P480A | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57473511; called by muse, mutect2, varscan2
- MECR | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55286209; called by muse, mutect2, varscan2
- MFHAS1 | c.2999-1G>T p.X1000_splice | Splice Site (SNP) | VAF 42/107 reads (39%) | catalogued as COSV52284202; called by muse, mutect2, varscan2
- MFN1 | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 57/75 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV54939336; called by muse, mutect2, varscan2
- MOGS | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV51970396; called by muse, mutect2, varscan2
- NCKAP1 | c.3146G>A p.G1049E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.038); catalogued as COSV62941956; called by muse, mutect2, varscan2
- ORMDL3 | c.399C>G p.S133R | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV58345860, COSV58345875, COSV58346013; called by muse, mutect2, varscan2
- RCOR3 | c.305G>C p.S102T | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs749916028, COSV65366149; called by muse, mutect2
- SETX | c.6218T>C p.L2073S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.958); catalogued as COSV56388835; called by muse, mutect2, varscan2
- SIGLEC5 | c.871A>T p.T291S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.214); catalogued as COSV55781147; called by muse, mutect2, varscan2
- SUSD2 | c.2234C>A p.S745Y | Missense Mutation (SNP) | VAF 123/316 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64204552; called by muse, mutect2, varscan2
- TAF3 | c.2163G>C p.K721N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as COSV60208246; called by muse, mutect2
- TGIF2 | c.469C>A p.L157M | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.466); catalogued as COSV65836652; called by muse, mutect2, varscan2
- TRANK1 | c.6512G>A p.R2171H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs370553712; called by muse, mutect2, varscan2
- XRN1 | c.4946G>A p.S1649N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.009); catalogued as rs752816625, COSV53814255; called by muse, mutect2
- ZAN | c.3205C>G p.L1069V | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV61811290; called by muse, mutect2, varscan2
- ZNF227 | c.742A>T p.K248* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV57312928; called by muse, mutect2, varscan2
- BAP1 | c.971del p.P324Hfs*11 | Frame Shift Del (DEL) | VAF 44/87 reads (51%) | called by pindel, varscan2
- CCDC168 | c.945dup p.T316Yfs*2 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- CNNM1 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, varscan2
- GBF1 | c.2027del p.K676Sfs*19 (on ENST00000369983 / NM_001377137.1; = p.K675Sfs*19 on NM_004193.3) | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- HNF4A | c.1111dup p.Q371Pfs*49 | Frame Shift Ins (INS) | VAF 45/150 reads (30%) | called by mutect2, pindel, varscan2
- LAMA3 | c.8526_8529delinsTA p.Y2843Nfs*23 (on ENST00000313654 / NM_198129.4; = p.Y1234Nfs*23 on NM_000227.6) | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | called by pindel, varscan2*
- PPWD1 | c.780del p.N262Mfs*2 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- ACADSB | c.489G>A p.L163= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs1564751488, COSV62551030; called by muse, mutect2, varscan2
- ATAD5 | c.990T>A p.P330= | Silent (SNP) | VAF 72/159 reads (45%) | catalogued as COSV58976193; called by muse, mutect2, varscan2
- DENND11 | c.891T>A p.P297= | Silent (SNP) | VAF 59/176 reads (34%) | catalogued as COSV72097719; called by muse, mutect2, varscan2
- FGG | c.1305A>G p.R435= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs757607080, COSV60195858; called by muse, mutect2, varscan2
- GPR37L1 | c.1119C>T p.L373= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV66162514; called by muse, mutect2
- IMMP2L | c.57C>T p.F19= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV104405075, COSV59249185; called by muse, mutect2, varscan2
- PTPRC | c.1140C>T p.N380= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as rs200643724; ClinVar: likely benign; called by muse, mutect2, varscan2
- SDCCAG8 | c.15G>A p.P5= | Silent (SNP) | VAF 7/122 reads (6%) | catalogued as rs922791738, COSV59412310; called by muse, mutect2
- THSD7A | c.891C>T p.R297= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs375820480; called by muse, mutect2, varscan2
- TNXB | c.4164G>A p.P1388= (on ENST00000647633; = p.P1141= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/138 reads (36%) | catalogued as rs747263738, COSV64482505; called by muse, mutect2, varscan2
- TPI1 | c.99C>T p.L33= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as rs375712848; called by muse, mutect2
- ZC3H3 | c.2574C>A p.P858= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV52791658; called by muse, mutect2, varscan2
- AC073140.1 | n.71T>C | RNA (SNP) | VAF 60/172 reads (35%) | catalogued as rs374460675; called by muse, mutect2, varscan2
- CNKSR2 | c.2693-7285G>A | Intron (SNP) | VAF 36/44 reads (82%) | catalogued as rs761171197, COSV99668027; called by mutect2, varscan2
